Surgical pathology report (de-identified scan), TCGA case TCGA-AD-6888, project TCGA-COAD (Colon Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AD-6888-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology

Histopathological Examination

Pre-Op Diagnosis : Lap Rt Colon Resection
Order Physician :
Specimens : Colon segment, right colon
Frozen Diagnosis :

Report : GROSS EXAMINATION:

The specimen is received fresh in a container labeled with the name of the patient and identified as colon segment, right colon.
Length of Terminal Ileum: 10.5 cm
Circumference of Terminal Ileum: 4.9 cm
Length of Colon: 36.5 cm
Circumference of Colon: 9 cm
Margins: Stapled
Serosa: A 2.5 x 1.8 cm puckered area in the ascending colon located 12 cm from the distal margin.
Mass #1:
Size: 6.4 x 4.5 x 1.2 cm
Type: Infiltrative with raised edges
Region: Cecum
Distance from proximal margin: 10.5 cm
Circumference: 50%
Depth of Invasion: 0.6 cm
Distance from Radial Margin: 2.2 cm
Mass #2:
Size: 7.8 x 5 x 1.1 cm
Type: Infiltrative with raised edges
Region: Ascending colon
Distance from distal margin: 9.7 cm
Circumference: 90%
Depth of Invasion: 0.3 cm
Distance from Radial Margin: 0.9 cm
There is a 1.2 cm pink polyp located 1.7 cm distal to the cecal mass and a 0.4 cm tan polyp located 1.6 cm from the ascending mass.
Appendix: Absent.
Block Summary: 1, cecal mass and radial margin; 2-4,

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #:
Visit #:

Page 1 of 3

[page 2 of 3]
additional sections of cecal mass; 5, ascending mass and radial margin; 6, ascending mass and serosa (black ink); 7-8, additional sections of ascending mass; 9, proximal polyp; 10, distal polyp; 11, proximal margin; 12, distal margin; 13-15, lymph nodes. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

Extended right hemicolectomy (36.5 cm):

- Colonic adenocarcinoma, 6.4 cm, high-grade, with extension through the muscularis propria (pT3) involving the cecum (see summary template).
- Colonic adenocarcinoma, 7.8 cm, low-grade, with extension through the muscularis propria (pT3) involving the ascending colon at the hepatic flexure (see summary template).
- Lymphovascular invasion identified.
- Tubular adenomas x 2.
- Margins of resection are free of carcinoma.
- [T-59600 M-81403 154.1 P3-44090]

COLON AND RECTUM: Resection

SPECIMEN: Terminal ileum, cecum, and ascending colon.

PROCEDURE: Right hemicolectomy.

SPECIMEN LENGTH:

Terminal ileum: 4.9 cm

Colon: 36.5 cm

TUMOR SITE: Cecum and hepatic flexure.

TUMOR SIZE: 6.4 cm and 7.8 cm

MACROSCOPIC TUMOR PERFORATION: Not identified.

HISTOLOGIC TYPE: Adenocarcinoma.

HISTOLOGIC GRADE:

High-grade (poorly differentiated) in cecum

Low-grade (well to moderately differentiated) at hepatic flexure.

HISTOLOGIC FEATURES SUGGESTIVE OF MICROSATELLITE

INSTABILITY:

Intratumoral lymphocytic response: Mild to moderate.

Peritumoral lymphocytic response: Mild to moderate.

Tumor subtype and differentiation: High histologic grade (poorly differentiated).

MICROSCOPIC TUMOR EXTENSION: Tumor invades through the muscularis propria into subserosal adipose tissue.

MARGINS:

Proximal, distal, and radial margins uninvolved by invasive carcinoma.

Closest margin: 0.9 cm (radial margin) at hepatic flexure mass.

TREATMENT EFFECT: No prior treatment.

LYMPH-VASCULAR INVASION: Present.

PERINEURAL INVASION: Not identified.

TUMOR DEPOSITS: Not identified.

PATHOLOGIC STAGING (pTNM):

TNM Descriptors: m (multiple primary tumors)

Primary Tumor (pT): pT3 (Tumor invades through the muscularis propria into peri colorectal tissues).

Regional Lymph Nodes (pN): pN1b (Metastases in 2-3 regional lymph nodes).

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #: [REDACTED]
Visit #: [REDACTED]

Page 2 of 3

[page 3 of 3]
Number examined: 18
Number involved: 2
Distant Metastasis (pM): N/A
ADDITIONAL PATHOLOGIC FINDINGS: Adenomas, x 2.
pTNM SUMMARY: pT3N1b (both lesions)

COMMENT: Intradepartmental consultation obtained.

[REDACTED]

[REDACTED]

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

[REDACTED] Path #: [REDACTED]
Visit #: [REDACTED]

Page 3 of 3

Source: NCI Genomic Data Commons file af964f36-7f1e-4522-bcc0-8e1504e9c9c3 (TCGA-AD-6888.BC82E9BE-543C-401F-87EE-3414FFEC3C14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).